TCGA case TCGA-08-0522 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/51e5a60f-e7b1-4b8b-b0b1-447c28940fe6

Demographics
Sex at birth: male; Race: white; Age at index: 61 years; Vital status: Dead; Days to death: 635 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 61.4 years (22,414 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 65 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 65 days; Number of cycles: 1; Treatment dose: 140 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 225 days; Number of cycles: 4; Treatment dose: 280 mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cintredekin Besudotox; Initial disease status: Progressive Disease; Days to treatment start: 268 days; Days to treatment end: 271 days; Treatment dose: 1 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Enzastaurin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 423 days (1.2 years); Days to treatment end: 511 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 517 days (1.4 years); Days to treatment end: 555 days (1.5 years); Number of cycles: 1; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 62.1 years (22,680 days); Days to diagnosis: 266 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 266 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 266 (post initial treatment): Progression or recurrence: Yes; Days to progression: 266 days.
- Days to follow up: 555 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 635 days (1.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-08-0522-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 45; Percent stromal cells: 10.
  Slide TCGA-08-0522-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 10.
- Sample TCGA-08-0522-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: IL-13-PE38QQR Cytoxin.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: LY317615.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 635 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 635 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 266 days.
